Gene-level copy-number profile of specimen HCM-WCMC-0675-C67-85R from HCMI case HCM-WCMC-0675-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage X; Tumor grade: GX; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-WCMC-0675-C67-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 15.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 496a2b2e-1f0b-4261-8c63-9e5e77e96671.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0675-C67-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/7d1ff9ef-e0a7-4069-a0de-2197cd9a70de

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 153; copy number 2: 7,442; copy number 3: 21,442; copy number 4: 21,163; copy number 5: 6,487; copy number 6: 1,846; copy number 7: 375; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 377 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:92,151–218,153, 6 genes, copy number 7: PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3.
- chr5:470,456–524,449, 1 gene, copy number 7 (within-gene range 6–7): SLC9A3.
- chr5:524,109–612,210, 3 genes, copy number 7: AC106772.2, MIR4456, AC106772.1.
- chr5:795,606–1,112,063, 12 genes, copy number 7: ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635.
- chr5:1,456,480–1,551,710, 3 genes, copy number 7: LPCAT1, MIR6075, AC091849.2.
- chr5:7,239,781–7,391,907, 9 genes, copy number 7: Metazoa_SRP, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142.
- chr5:7,830,378–7,851,151, 1 gene, copy number 7: C5orf49.
- chr5:8,080,186–8,080,761, 1 gene, copy number 7: AC091941.1.
- chr5:8,614,356–10,082,772, 31 genes, copy number 7: AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4.
- chr5:10,225,507–10,777,062, 30 genes, copy number 7: ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1.
- chr5:12,297,399–18,746,173, 102 genes, copy number 7 (broad region; genes not listed).
- chr5:19,233,366–19,234,487, 1 gene, copy number 7: HSPD1P15.
- chr5:20,606,710–20,937,800, 2 genes, copy number 7 (within-gene range 6–7): LINC02146, LINC02241.
- chr5:21,616,262–21,779,522, 1 gene, copy number 7 (within-gene range 6–7): AC091946.1.
- chr5:26,880,597–27,121,150, 1 gene, copy number 7 (within-gene range 6–7): CDH9.
- chr5:29,304,305–29,600,868, 3 genes, copy number 7: LINC02064, AC027345.1, UBL5P1.
- chr5:31,093,977–31,329,146, 3 genes, copy number 7: AC113386.1, CDH6, DUX4L51.
- chr5:32,103,445–32,791,724, 14 genes, copy number 7 (within-gene range 6–7): AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, NPR3.
- chr5:32,888,236–33,298,066, 1 gene, copy number 7 (within-gene range 6–7): AC010343.3.
- chr5:33,008,934–35,896,290, 44 genes, copy number 7–8: AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160, AC034231.1, TARS1, TOMM40P3, AC034232.1, ADAMTS12, RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1, AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1, U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1.
- chr5:35,951,006–37,753,435, 33 genes, copy number 7: UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P.
- chr5:37,899,363–38,198,148, 6 genes, copy number 7: LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1.
- chr5:38,845,858–40,798,374, 19 genes, copy number 7 (within-gene range 6–7): OSMR, RICTOR, AIG1P1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, TTC33, SNORA63, PTGER4, PRKAA1.
- chr5:40,909,497–42,191,523, 17 genes, copy number 7: C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1.
- chr5:43,192,071–43,525,310, 14 genes, copy number 7: NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1.
- chr5:43,874,367–44,066,731, 2 genes, copy number 7: AC104119.1, RNU6-381P.
- chr14:38,605,255–39,183,220, 16 genes, copy number 7: AL357094.1, KRT8P1, LINC00639, AL132994.1, AL132994.2, Y_RNA, SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN.
- chr22:23,926,900–23,929,574, 1 gene, copy number 7: AP000350.2.

Autosomal genes at a single copy (total copy number 1): 153. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
